Somatic mutation profile of tumor specimen TCGA-IB-A7M4-01A (aliquot TCGA-IB-A7M4-01A-11D-A36O-08) from TCGA case TCGA-IB-A7M4, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 81.6 years (29,792 days).
Specimen TCGA-IB-A7M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54438d67-4d20-4266-8015-116771f15f8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-A7M4-10A (Blood Derived Normal), aliquot TCGA-IB-A7M4-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4519f138-a8b5-4cea-9cfc-75a9f304b65a

The open-access MAF lists 59 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 10, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 91/422 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 71/222 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BMP2 | c.961C>G p.H321D | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV101122104, COSV66578995; called by muse, mutect2
- BRINP2 | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 89/374 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768682042, COSV64179715; called by muse, mutect2, varscan2
- CIAO1 | c.282C>G p.D94E | Missense Mutation (SNP) | VAF 116/464 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99302682; called by muse, mutect2, varscan2
- CLTC | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 110/529 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99291501, COSV99292617; called by muse, mutect2, varscan2
- CPNE5 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1291036163, COSV99783064; called by muse, mutect2, varscan2
- CSPG4 | c.3998C>T p.S1333L | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs767886749, COSV100413689; called by muse, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 20/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2
- DMXL1 | c.6065A>C p.D2022A | Missense Mutation (SNP) | VAF 64/348 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100224455; called by muse, mutect2, varscan2
- DST | c.22004C>T p.T7335M (on ENST00000361203 / NM_001374722.1; = p.T5045M on NM_015548.5) | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs532258725, COSV99758258; called by muse, mutect2, varscan2
- ELMO1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767018272, COSV60302807; called by muse, mutect2
- ETV6 | c.1037A>G p.Y346C | Missense Mutation (SNP) | VAF 172/931 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765564; called by muse, mutect2, varscan2
- HM13 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 71/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100159668; called by muse, mutect2, varscan2
- IGSF9B | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 75/295 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs534012086, COSV100318057; called by muse, mutect2, varscan2
- ITGA6 | c.3007-1G>A p.X1003_splice (on ENST00000442250; = p.X964_splice on NM_000210.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/373 reads (4%) | catalogued as COSV51228372, COSV99905767; called by muse, mutect2
- IVL | c.320A>G p.Q107R | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV100908211; called by muse, mutect2, varscan2
- LOX | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 70/1138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99140661; called by muse, mutect2
- LRBA | c.8365C>T p.R2789* | Nonsense Mutation (SNP) | VAF 14/320 reads (4%) | catalogued as COSV100841931; called by muse, mutect2
- MICAL2 | c.1698C>G p.D566E | Missense Mutation (SNP) | VAF 14/518 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99817980; called by muse, mutect2
- MUC2 | c.934G>A p.V312M | Missense Mutation (SNP) | VAF 81/364 reads (22%) | SIFT deleterious (0); catalogued as rs897904604, COSV100364584; called by muse, mutect2, varscan2
- MYO7B | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as rs377172629; called by muse, mutect2, varscan2
- NHS | c.3631G>C p.E1211Q | Missense Mutation (SNP) | VAF 15/406 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV101196794; called by muse, mutect2
- NPHP3 | c.3083G>A p.R1028H | Missense Mutation (SNP) | VAF 78/964 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs200722938, COSV100447126; called by muse, mutect2
- OR5B17 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.081); catalogued as rs1156486687, COSV100641937, COSV62160149; called by muse, mutect2, varscan2
- OR6C6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 87/326 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs757658611, COSV64456046; called by muse, mutect2, varscan2
- PCDHGA2 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 49/969 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.033); catalogued as rs746420859, COSV54006428, COSV54036882; called by muse, mutect2
- PHACTR1 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 42/954 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763375632, COSV100278009; called by muse, mutect2
- PITPNM2 | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 144/581 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV99759316; called by muse, mutect2, varscan2
- PLXNA2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 117/495 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771808559, COSV65438490; called by muse, mutect2, varscan2
- PTPDC1 | c.125A>G p.E42G (on ENST00000375360 / NM_177995.3; = p.E94G on NM_152422.4) | Missense Mutation (SNP) | VAF 163/745 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1293813225, COSV99997786; called by muse, mutect2, varscan2
- PWP1 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 36/754 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV101338843; called by muse, mutect2
- RASGRF2 | c.1017T>G p.F339L | Missense Mutation (SNP) | VAF 57/896 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99429794; called by muse, mutect2
- RPL14 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1395140596, COSV100166260; called by muse, mutect2, varscan2
- SCN9A | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 30/460 reads (7%) | catalogued as rs1448265143, COSV100313383; called by muse, mutect2
- SCRIB | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 31/514 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs370311838, COSV57587020; called by muse, mutect2
- STIL | c.1168A>G p.I390V | Missense Mutation (SNP) | VAF 99/487 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99681147; called by muse, mutect2, varscan2
- TANGO6 | c.857G>T p.C286F | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.556); catalogued as COSV99936637; called by muse, mutect2, varscan2
- TENM3 | c.6683G>A p.R2228H | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as rs201200379, COSV69300412; called by muse, mutect2
- TMTC3 | c.1201G>A p.V401I | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as COSV57126409; called by muse, mutect2, varscan2
- VDAC2 | c.337A>G p.T113A | Missense Mutation (SNP) | VAF 102/484 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100041027; called by muse, mutect2, varscan2
- WASF3 | c.1381C>T p.R461W | Missense Mutation (SNP) | VAF 61/346 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.91); catalogued as rs1269927215, COSV100099104; called by muse, mutect2, varscan2
- ZNF569 | c.1835G>A p.G612E | Missense Mutation (SNP) | VAF 180/723 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100386555; called by muse, mutect2, varscan2
- ZNF773 | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 101/517 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.154); catalogued as rs774985702, COSV56588485, COSV99989437; called by muse, mutect2, varscan2
- ANKRD13C | c.111del p.F38Lfs*26 | Frame Shift Del (DEL) | VAF 75/481 reads (16%) | called by mutect2, pindel, varscan2
- PER1 | c.1864dup p.S622Kfs*27 | Frame Shift Ins (INS) | VAF 36/267 reads (13%) | called by mutect2, pindel, varscan2
- RPL15 | c.338dup p.R114Efs*10 | Frame Shift Ins (INS) | VAF 105/440 reads (24%) | called by mutect2, pindel, varscan2
- TNXB | c.8933del p.P2978Rfs*12 (on ENST00000647633; = p.P2731Rfs*12 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 75/327 reads (23%) | called by mutect2, pindel, varscan2
- AGL | c.4413G>A p.P1471= | Silent (SNP) | VAF 19/335 reads (6%) | catalogued as rs1049817296, COSV54050675; ClinVar: likely benign; called by muse, mutect2
- CSMD3 | c.6852T>A p.G2284= (on ENST00000297405 / NM_001363185.1; = p.G2180= on NM_052900.3) | Silent (SNP) | VAF 174/505 reads (34%) | catalogued as COSV99840791; called by muse, mutect2, varscan2
- FAM133A | c.555T>C p.P185= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV100220529; called by muse, mutect2
- FTMT | c.519G>A p.S173= | Silent (SNP) | VAF 33/602 reads (5%) | catalogued as rs772478687, COSV58419816; called by muse, mutect2
- MTUS2 | c.1443G>A p.T481= | Silent (SNP) | VAF 41/219 reads (19%) | catalogued as rs201515125; called by muse, mutect2, varscan2
- PKD1 | c.3714C>T p.G1238= | Silent (SNP) | VAF 53/188 reads (28%) | catalogued as rs769745056, COSV51927308; called by muse, mutect2, varscan2
- PPIAL4A | c.33C>T p.T11= | Silent (SNP) | VAF 112/625 reads (18%) | called by muse, mutect2, varscan2
- SEMA6A | c.2454G>A p.L818= | Silent (SNP) | VAF 37/508 reads (7%) | catalogued as COSV99145850; called by muse, mutect2
- SMCR8 | c.1134C>T p.V378= | Silent (SNP) | VAF 90/349 reads (26%) | catalogued as rs1217289925, COSV100329217; called by muse, mutect2, varscan2
- WIPF1 | c.948C>T p.P316= | Silent (SNP) | VAF 35/189 reads (19%) | catalogued as rs779265386, COSV99769046; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504515 T>A | 5'Flank (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
